Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3977, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3977-01A (Primary Tumor).

Diagnosis:

Resected colon (sigma) sample with tumor-free oral and aboral resection margins, with a tubular adenoma displaying moderate dysplasia (synonym: low-grade intraepithelial neoplasia) and including a moderately differentiated adenocarcinoma with infiltration of the lamina muscularis propria. No local lymph node metastasis (G2, pT2 L0 V0 R0 pN0 0/15).

Source: NCI Genomic Data Commons file 0faaf06e-5d2d-4b96-956c-40a920f87461 (TCGA-AA-3977.0AF2B6CB-F718-4D12-B444-2FEB4730EA27.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).